Somatic mutation profile of tumor specimen TCGA-85-7950-01A (aliquot TCGA-85-7950-01A-11D-2184-08) from TCGA case TCGA-85-7950, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 46.5 years (16,975 days).
Specimen TCGA-85-7950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad4575ec-42ab-45c9-bab1-4df764c8997a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-7950-10A (Blood Derived Normal), aliquot TCGA-85-7950-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c888b7a-d647-4b1e-9db9-43a26f44d831

The open-access MAF lists 290 somatic variants for this specimen: 228 protein-altering or splice-affecting, 55 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 55, Nonsense Mutation 12, Frame Shift Del 7, Splice Site 5, Splice Region 3, Frame Shift Ins 2, Intron 2, In Frame Del 2, RNA 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL4 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345325140, CM159506, COSV57747562; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRUNE1 | c.521-2A>G p.X174_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as rs886039608, COSV99639915; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 54/80 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4708G>T p.D1570Y | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV100217686; called by muse, mutect2, varscan2
- ABCC8 | c.4707G>T p.K1569N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100217690; called by muse, mutect2, varscan2
- AFF3 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV57848308; called by muse, mutect2, varscan2
- AFTPH | c.1579A>G p.K527E | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV99481176; called by muse, mutect2, varscan2
- ANKS1B | c.3672G>A p.V1224= (on ENST00000547776 / NM_152788.4; = p.V390= on NM_020140.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100228817; called by muse, mutect2, varscan2
- ANKS1B | c.2420-1G>T p.X807_splice (on ENST00000547776 / NM_152788.4; = p.G33* on NM_020140.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/69 reads (38%) | catalogued as COSV100228820; called by muse, mutect2, varscan2
- AP1S3 | c.55T>C p.W19R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100525420; called by muse, mutect2, varscan2
- AP2A2 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs1233326852, COSV100173307; called by muse, mutect2, varscan2
- ARNT | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.44); catalogued as COSV100591352; called by muse, mutect2, varscan2
- ASB13 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100731412; called by muse, mutect2, varscan2
- ASGR2 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs767191672, COSV54689161, COSV54691237; called by muse, mutect2, varscan2
- ATXN3L | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV101019578; called by muse, mutect2, varscan2
- B3GALT5 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100563467; called by muse, mutect2, varscan2
- C2CD2L | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757458542, COSV60884131; called by muse, mutect2, varscan2
- C2orf16 | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.075); catalogued as COSV101284417; called by muse, mutect2, varscan2
- C8B | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64779546; called by muse, mutect2, varscan2
- CACHD1 | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV51556237, COSV99263213; called by muse, mutect2, varscan2
- CACNA1A | c.3422C>A p.P1141H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs200333359, COSV100803137; called by muse, mutect2, varscan2
- CACNA1F | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545345, COSV59904712; called by muse, mutect2, varscan2
- CACNG1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs760216442, COSV56826298, COSV56827091; called by muse, mutect2, varscan2
- CACNG2 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV100269050; called by muse, mutect2, varscan2
- CAPN11 | c.1917del p.W639* | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as COSV67237115; called by mutect2, pindel, varscan2
- CASR | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.242); catalogued as COSV99949421; called by muse, mutect2, varscan2
- CBL | c.1697C>A p.P566H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50635798, COSV99876967; called by muse, mutect2, varscan2
- CCDC163 | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs771294449, COSV101284473; called by muse, mutect2, varscan2
- CD163 | c.1087G>T p.V363L | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100776099, COSV63134186; called by muse, mutect2, varscan2
- CDCP2 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100313660; called by muse, mutect2, varscan2
- CDKL2 | c.720G>T p.L240F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100277179; called by muse, mutect2, varscan2
- CHD7 | c.5222G>A p.R1741H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1376563036, CM112407, COSV101418415; called by muse, mutect2, varscan2
- CHL1 | c.1659T>A p.S553R (on ENST00000397491 / NM_001253387.1; = p.S569R on NM_006614.4) | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99849626; called by muse, mutect2, varscan2
- CHRNA2 | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99532480; called by muse, mutect2, varscan2
- CKAP2L | c.1775G>C p.R592P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100198759; called by muse, mutect2, varscan2
- CLCA1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322766; called by muse, mutect2, varscan2
- CLEC17A | c.542T>A p.L181Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100355560; called by muse, varscan2
- CNTN4 | c.2963G>C p.R988P | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100638916, COSV100639686, COSV61868753; called by muse, mutect2, varscan2
- CNTNAP2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV100671653; called by muse, varscan2
- COL8A1 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658394; called by muse, mutect2
- COPB2 | c.2484G>A p.T828= | Splice Region (SNP) | VAF 46/193 reads (24%) | catalogued as rs1162553959, COSV100169219; called by muse, mutect2, varscan2
- CPSF1 | c.3910G>A p.V1304M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs782548508, COSV58231973; called by muse, mutect2, varscan2
- CSMD1 | c.1253G>T p.G418V (on ENST00000520002; = p.G417V on NM_033225.6) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101224657; called by muse, mutect2, varscan2
- CSMD1 | c.1252G>C p.G418R (on ENST00000520002; = p.G417R on NM_033225.6) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101224658; called by muse, mutect2, varscan2
- CSMD3 | c.10993T>A p.C3665S (on ENST00000297405 / NM_001363185.1; = p.C3496S on NM_052900.3) | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV52098297, COSV99846526; called by muse, mutect2, varscan2
- CSRNP3 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV100086269; called by muse, mutect2, varscan2
- CTSK | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.4); catalogued as COSV99648961; called by muse, mutect2, varscan2
- CYP11A1 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 82/124 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99166154; called by muse, mutect2, varscan2
- CYP11B2 | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100011354; called by muse, mutect2, varscan2
- CYP27A1 | c.744C>G p.F248L | Missense Mutation (SNP) | VAF 85/492 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as COSV99298726; called by muse, mutect2, varscan2
- DCAF8L1 | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101491540, COSV71595524; called by muse, mutect2, varscan2
- DDHD1 | c.1853T>C p.L618S (on ENST00000323669; = p.L815S on NM_030637.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100080005; called by muse, mutect2, varscan2
- DENND2B | c.1895G>C p.R632T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV100567806; called by muse, mutect2, varscan2
- DOCK2 | c.5043G>T p.E1681D | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99915085; called by muse, mutect2, varscan2
- DPP6 | c.1620C>A p.S540R (on ENST00000377770 / NM_001364500.2; = p.S478R on NM_001936.5) | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV100127928; called by muse, mutect2, varscan2
- DPPA4 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV100169694; called by muse, mutect2, varscan2
- DSEL | c.282G>T p.L94F | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.561); catalogued as COSV100026069; called by muse, mutect2, varscan2
- DTD1 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as COSV101080052; called by muse, mutect2, varscan2
- DZANK1 | c.1004G>C p.G335A (on ENST00000262547 / NM_001099407.1; = p.G136A on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99363172; called by muse, mutect2, varscan2
- ENPEP | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as rs1326994952, COSV99488085; called by muse, mutect2, varscan2
- EPHB6 | c.2464C>G p.P822A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV63893711; called by muse, mutect2, varscan2
- FAT1 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.195); catalogued as COSV101499628; called by muse, mutect2, varscan2
- FAT1 | c.1495A>G p.T499A | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71674378; called by muse, varscan2
- FAT3 | c.6082A>G p.I2028V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV99970592; called by muse, mutect2, varscan2
- FCRL3 | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100943520; called by muse, mutect2, varscan2
- FER | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.996); catalogued as COSV99813856; called by muse, mutect2, varscan2
- FNDC1 | c.5386G>T p.V1796L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99796685; called by muse, mutect2, varscan2
- FOXF2 | c.605C>A p.A202E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99453472; called by muse, mutect2, varscan2
- GALNT7 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.995); catalogued as rs935972665, COSV99397775; called by muse, mutect2, varscan2
- GPC2 | c.1000A>C p.N334H | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99445060; called by muse, mutect2, varscan2
- GPR158 | c.2761C>G p.Q921E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as rs1371069810, COSV100894243, COSV66273532; called by muse, mutect2, varscan2
- GPR22 | c.1121T>G p.F374C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99773105; called by muse, mutect2, varscan2
- GPRC5C | c.781G>A p.V261I (on ENST00000652232; = p.V216I on NM_018653.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs757205835, COSV61236250; called by muse, mutect2, varscan2
- GTF3C3 | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV99826982; called by muse, varscan2
- HAL | c.1602G>T p.M534I | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701614; called by muse, mutect2, varscan2
- HDGFL1 | c.27C>G p.Y9* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100014720; called by muse, mutect2, varscan2
- HDX | c.835G>T p.G279* | Nonsense Mutation (SNP) | VAF 49/71 reads (69%) | catalogued as COSV99947985; called by muse, mutect2, varscan2
- HEPACAM2 | c.616A>T p.I206F (on ENST00000394468 / NM_001039372.4; = p.I194F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100506779; called by muse, mutect2, varscan2
- HLX | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV100854616; called by muse, mutect2
- HPF1 | c.324T>G p.F108L | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV101097702; called by muse, mutect2, varscan2
- HTR5A | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV99839958; called by muse, mutect2, varscan2
- HYDIN | c.6179A>G p.Y2060C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99993605; called by mutect2, varscan2
- IFNG | c.144T>A p.N48K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99971272; called by muse, mutect2, varscan2
- IFTAP | c.652A>C p.K218Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100531360; called by muse, mutect2, varscan2
- IGKV3-20 | c.244A>G p.R82G | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs573570457; called by muse, mutect2, varscan2
- IHH | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs201214780, COSV99838792; called by muse, mutect2, varscan2
- IMPDH1 | c.872A>T p.Q291L (on ENST00000470772 / NM_001142573.2; = p.Q377L on NM_000883.4) | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100118796, COSV58314782; called by muse, mutect2, varscan2
- IP6K1 | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100390095; called by muse, mutect2, varscan2
- ITPKB | c.2061G>T p.R687S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV99685125; called by muse, mutect2, varscan2
- KAT6A | c.5632A>T p.S1878C | Missense Mutation (SNP) | VAF 212/232 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV99705817; called by muse, mutect2, varscan2
- KCNAB1 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV101051438; called by muse, mutect2, varscan2
- KIAA0100 | c.2018del p.P673Qfs*20 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | catalogued as rs1567659088, COSV66496054; called by mutect2, pindel, varscan2
- KIAA1841 | c.939G>C p.L313F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99694204; called by muse, mutect2, varscan2
- KIF13B | c.2125A>G p.K709E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV101580791; called by muse, mutect2, varscan2
- KLHL2 | c.1338A>C p.G446= | Splice Region (SNP) | VAF 26/143 reads (18%) | catalogued as COSV99900299; called by muse, mutect2, varscan2
- KNL1 | c.3580G>A p.D1194N (on ENST00000346991 / NM_170589.5; = p.D1168N on NM_144508.5) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1212794609, COSV61152662; called by muse, mutect2, varscan2
- KRCC1 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100712869; called by muse, mutect2, varscan2
- LAG3 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV99180004; called by muse, mutect2, varscan2
- LAIR2 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.887); catalogued as COSV100003428; called by muse, mutect2, varscan2
- LCMT2 | c.1220G>C p.S407T | Missense Mutation (SNP) | VAF 122/190 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs767666563, COSV99980221; called by muse, mutect2, varscan2
- LDLRAD2 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100760923, COSV60829253; called by muse, mutect2
- LDLRAP1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776857764, COSV65473137; called by muse, mutect2, varscan2
- LRP12 | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747847767, COSV99408307; called by muse, mutect2, varscan2
- LRP1B | c.4449C>A p.Y1483* | Nonsense Mutation (SNP) | VAF 20/132 reads (15%) | catalogued as COSV101260358; called by muse, mutect2, varscan2
- LRP1B | c.4168G>T p.G1390* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV101260360; called by muse, mutect2, varscan2
- LRP2BP | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100146038; called by muse, mutect2, varscan2
- LRRC4B | c.775T>A p.W259R | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV100976034; called by muse, mutect2, varscan2
- MANSC1 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101115909; called by muse, mutect2, varscan2
- MORF4L1 | c.632G>A p.W211* (on ENST00000331268 / NM_206839.2; = p.W172* on NM_006791.4) | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100489202; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV100187154; called by muse, mutect2, varscan2
- MUC16 | c.24155C>T p.P8052L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.076); catalogued as COSV101200389, COSV67464425; called by muse, mutect2, varscan2
- MXRA5 | c.7957G>C p.E2653Q | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV99479054; called by muse, mutect2, varscan2
- MYBBP1A | c.624A>G p.I208M | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as rs1376104555, COSV99626859; called by muse, mutect2, varscan2
- MYH8 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV101238727; called by muse, mutect2, varscan2
- MYO16 | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.483); catalogued as COSV51796608, COSV99193818; called by muse, mutect2, varscan2
- NKX2-2 | c.629G>T p.R210M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101010526; called by muse, mutect2, varscan2
- NLRP4 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100017093; called by muse, mutect2, varscan2
- NLRP9 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100243401; called by muse, mutect2, varscan2
- NXPH2 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs558833211, COSV99741274; called by muse, mutect2, varscan2
- OFD1 | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV100366513; called by muse, mutect2, varscan2
- OLFM4 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54577591, COSV99524549; called by muse, mutect2, varscan2
- OR10Q1 | c.22T>A p.F8I | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100372386; called by muse, mutect2, varscan2
- OR2M3 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101513512; called by muse, mutect2, varscan2
- OR4K15 | c.966G>C p.M322I (on ENST00000305051; = p.M298I on NM_001005486.1) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV100521153; called by muse, mutect2, varscan2
- OR6C74 | c.347T>A p.M116K | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100667842; called by muse, mutect2, varscan2
- OR6F1 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57467597; called by muse, mutect2, varscan2
- OR6K6 | c.755T>A p.I252N (on ENST00000368144; = p.I228N on NM_001005184.1) | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100933788; called by muse, mutect2, varscan2
- OR8J1 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as COSV100275176; called by muse, mutect2, varscan2
- OR8K5 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.194); catalogued as COSV100537315, COSV100537322; called by muse, mutect2, varscan2
- PABPC1 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100589842; called by muse, mutect2, varscan2
- PCDHGB2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV54017424; called by muse, mutect2, varscan2
- PCNX2 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV50805545; called by muse, mutect2, varscan2
- PDLIM3 | c.403G>C p.V135L (on ENST00000284770 / NM_001257963.1; = p.V302L on NM_014476.6) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99507842; called by muse, mutect2, varscan2
- PDZD7 | c.1312C>A p.L438M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100931705, COSV64647500; called by muse, mutect2
- PHF3 | c.2074G>C p.D692H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100013921; called by muse, mutect2, varscan2
- PIWIL2 | c.2836T>C p.Y946H | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100769535; called by muse, mutect2, varscan2
- PKD1L1 | c.5060A>G p.Q1687R | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as rs754383189, COSV99221272; called by muse, mutect2, varscan2
- POLB | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 32/793 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99613434; called by muse, mutect2
- PON3 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99672693; called by muse, mutect2, varscan2
- PPP2R2C | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100067219; called by muse, mutect2, varscan2
- PRSS16 | c.84G>C p.R28S | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100041961; called by muse, mutect2, varscan2
- PTEN | c.455del p.L152Qfs*7 | Frame Shift Del (DEL) | VAF 31/59 reads (53%) | catalogued as CM110157, COSV64298007, COSV64299684, COSV64301059; called by mutect2, pindel, varscan2
- PTPN3 | c.1949T>G p.F650C | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99356190; called by muse, mutect2, varscan2
- PTPN7 | c.982C>A p.L328I (on ENST00000495688; = p.L367I on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100460118; called by muse, mutect2
- PWP1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV101338853; called by muse, mutect2, varscan2
- RAPGEF5 | c.667C>T p.Q223* (on ENST00000401957 / NM_001367602.2; = p.Q526* on NM_012294.5) | Nonsense Mutation (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100687804; called by muse, mutect2, varscan2
- RASAL1 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV55660184, COSV99922088; called by muse, mutect2, varscan2
- RBM33 | c.3309G>C p.E1103D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV100355446; called by muse, varscan2
- RFX4 | c.251T>C p.M84T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.033); catalogued as COSV100774852; called by muse, mutect2, varscan2
- RNF133 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV100411748; called by muse, mutect2, varscan2
- ROBO4 | c.2632G>C p.G878R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100127849; called by muse, mutect2, varscan2
- ROPN1L | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.944); catalogued as rs1394581689, COSV56875327; called by muse, mutect2, varscan2
- RPS6KA2 | c.1489C>A p.R497S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV104378122, COSV99692015; called by muse, mutect2, varscan2
- RTTN | c.848T>G p.V283G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99733717; called by muse, mutect2, varscan2
- RYR2 | c.4751dup p.R1585Afs*29 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | catalogued as rs766543639; called by mutect2, pindel, varscan2
- SCYL2 | c.1471A>G p.R491G | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100675306; called by muse, mutect2, varscan2
- SEC16B | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV57624442; called by muse, mutect2, varscan2
- SEC23IP | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs368504293, COSV64832886; called by muse, mutect2, varscan2
- SEMA5B | c.2506+1G>T p.X836_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99533078; called by muse, mutect2, varscan2
- SEMA5B | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV99533083; called by muse, mutect2, varscan2
- SIGLEC1 | c.891G>T p.W297C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99170649; called by muse, mutect2, varscan2
- SIM1 | c.1369G>T p.V457L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.021); catalogued as COSV99492738; called by muse, varscan2
- SIX3 | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99578552; called by muse, mutect2
- SLC17A8 | c.547G>T p.G183* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as COSV100035839; called by muse, mutect2, varscan2
- SLC17A8 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as COSV100035841; called by muse, mutect2, varscan2
- SLC22A25 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.082); catalogued as COSV100123598, COSV100123937; called by muse, mutect2, varscan2
- SLC49A3 | c.808C>G p.L270V (on ENST00000404286 / NM_001294341.2; = p.L269V on NM_032219.4) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100448557; called by muse, mutect2, varscan2
- SLC4A9 | c.2101C>A p.R701S (on ENST00000507527 / NM_001258428.2; = p.R677S on NM_031467.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761539859, COSV50196986, COSV50229038; called by muse, mutect2, varscan2
- SMARCC1 | c.828C>G p.F276L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54383843, COSV99593424; called by muse, mutect2, varscan2
- SNAP91 | c.2114C>A p.P705H | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99536446, COSV99536677; called by muse, mutect2, varscan2
- SNX19 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99773571; called by muse, mutect2
- SOHLH1 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.6); PolyPhen benign (0.326); catalogued as COSV100040479; called by muse, mutect2, varscan2
- SPHKAP | c.807A>T p.E269D | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as COSV100764519; called by muse, mutect2, varscan2
- SPIRE2 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs146853123; called by muse, mutect2, varscan2
- SPTA1 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534906145, COSV63757502, COSV63762278; called by muse, mutect2, varscan2
- STYX | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754364637, COSV100648333; called by muse, mutect2, varscan2
- SUV39H1 | c.34T>G p.C12G | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100551843; called by muse, mutect2, varscan2
- SYNE1 | c.1491G>C p.E497D (on ENST00000367255 / NM_182961.4; = p.E504D on NM_033071.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV99577037; called by muse, mutect2, varscan2
- SYNE2 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100648432; called by muse, mutect2, varscan2
- TAS2R16 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as COSV99972345; called by muse, mutect2, varscan2
- TBC1D23 | c.54-1G>T p.X18_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100792738; called by muse, mutect2
- TENM3 | c.2611G>C p.V871L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV101305449; called by muse, mutect2, varscan2
- TENM3 | c.6703C>G p.R2235G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV101305450, COSV69299638; called by muse, mutect2, varscan2
- TEP1 | c.3338A>G p.Q1113R | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV99403166; called by muse, mutect2, varscan2
- TEX13A | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781885185, COSV100781901, COSV61144403; called by muse, mutect2, varscan2
- TEX35 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV99274970; called by muse, mutect2, varscan2
- TFB2M | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100830520; called by muse, mutect2, varscan2
- THBS2 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1242352683, COSV100828060; called by muse, mutect2, varscan2
- THSD7B | c.824A>T p.E275V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV99757691; called by muse, mutect2, varscan2
- TIGD3 | c.612G>T p.R204S | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.222); catalogued as COSV99361928; called by muse, mutect2, varscan2
- TMTC1 | c.1602G>T p.K534N (on ENST00000539277 / NM_001193451.2; = p.K426N on NM_175861.3) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs748290717, COSV55478845; called by muse, mutect2, varscan2
- TNXB | c.7247G>T p.G2416V (on ENST00000647633; = p.G2169V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100926609, COSV64472491; called by muse, mutect2, varscan2
- TOM1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV101147078; called by muse, mutect2, varscan2
- TPPP2 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100069458, COSV53875465; called by muse, mutect2, varscan2
- TRAF3IP1 | c.250T>A p.S84T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV100967064; called by muse, mutect2, varscan2
- TRPA1 | c.2756G>T p.R919L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as COSV100085110; called by muse, mutect2, varscan2
- TTN | c.82390A>T p.K27464* (on ENST00000591111; = p.K20040* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV100628140; called by muse, mutect2, varscan2
- TTN | c.41658G>A p.M13886I (on ENST00000591111; = p.M6462I on NM_003319.4) | Missense Mutation (SNP) | VAF 32/156 reads (21%) | PolyPhen probably damaging (0.961); catalogued as rs1310174493, COSV100628142; called by muse, mutect2, varscan2
- USH2A | c.5716A>T p.I1906F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100241973; called by muse, mutect2, varscan2
- USH2A | c.4226A>G p.Q1409R | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1203038826, COSV100241975; called by muse, mutect2, varscan2
- USH2A | c.2544C>A p.N848K | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV100241980; called by muse, mutect2, varscan2
- USP33 | c.2603-1G>T p.X868_splice | Splice Site (SNP) | VAF 55/96 reads (57%) | catalogued as COSV100657228; called by muse, mutect2, varscan2
- USP49 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99790602; called by muse, mutect2, varscan2
- VCAM1 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.112); catalogued as rs1389436211, COSV99658896; called by muse, mutect2, varscan2
- VCPIP1 | c.704G>T p.W235L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100125773; called by muse, mutect2, varscan2
- VEGFC | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); catalogued as COSV99710304; called by muse, mutect2, varscan2
- VWC2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs770578022, COSV100514700; called by muse, mutect2, varscan2
- VWC2L | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as COSV100436294; called by muse, mutect2, varscan2
- YLPM1 | c.1832C>G p.S611C | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.391); catalogued as COSV99461204; called by muse, mutect2, varscan2
- ZFHX4 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442063884, COSV51461080; called by muse, mutect2, varscan2
- ZIC1 | c.439C>A p.H147N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99292374; called by muse, mutect2, varscan2
- ZMYM4 | c.2687del p.P896Lfs*7 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | catalogued as COSV58910113; called by mutect2, pindel, varscan2
- ZNF439 | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100397561; called by muse, mutect2
- ZNF479 | c.120A>T p.L40F | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100483038; called by muse, mutect2, varscan2
- ZNF496 | c.1680G>T p.K560N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99666114; called by muse, mutect2, varscan2
- ZNF569 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100386623, COSV104394735; called by muse, mutect2, varscan2
- ZNF639 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV100418480; called by muse, mutect2, varscan2
- ZNF804B | c.3315G>T p.M1105I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV60820268; called by muse, mutect2, varscan2
- ADAMTS12 | c.1845del p.Y616Tfs*25 | Frame Shift Del (DEL) | VAF 32/140 reads (23%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.2553_2558del p.A852_A853del (on ENST00000506720 / NM_001322402.2; = p.A784_A785del on NM_015236.6) | In Frame Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- CD300LD | c.466del p.L156Sfs*23 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- GTF2IRD2B | c.1293G>T p.K431N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by mutect2, varscan2
- KRTAP10-7 | c.141C>A p.C47* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- OR10H4 | c.788del p.K263Sfs*13 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- POTEA | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 388/442 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- RHBG | c.1269_1270insA p.P424Tfs*19 | Frame Shift Ins (INS) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- SPACA5B | c.221A>T p.Y74F | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZBTB7C | c.1351_1359del p.E451_C453del | In Frame Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- ABHD18 | c.864C>T p.V288= (on ENST00000398965 / NM_001039717.2; = p.V195= on NM_025097.2 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs772970028, COSV101180836; called by muse, mutect2, varscan2
- ACTR3B | c.1200T>C p.Y400= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV99754474; called by muse, mutect2, varscan2
- ADAP1 | c.540G>A p.L180= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV99763367; called by muse, mutect2, varscan2
- AGAP2 | c.2892C>G p.L964= (on ENST00000547588 / NM_001122772.2; = p.L608= on NM_014770.4) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99224187; called by muse, varscan2
- AHNAK | c.4458C>T p.D1486= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV99949424; called by muse, mutect2, varscan2
- ANK2 | c.7548T>C p.S2516= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100003963; called by muse, mutect2, varscan2
- ARMCX2 | c.1050A>G p.S350= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs782363444, COSV100168299; called by muse, mutect2, varscan2
- CACNA1C | c.3816C>A p.A1272= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100221874, COSV59705012; called by muse, mutect2, varscan2
- CDH10 | c.1737A>C p.T579= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100052975; called by muse, mutect2, varscan2
- CEBPZ | c.1047C>T p.V349= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1386530786, COSV99135769; called by muse, mutect2, varscan2
- CENPF | c.4299A>T p.S1433= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100871946; called by muse, mutect2, varscan2
- CFAP47 | c.2451C>A p.P817= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV99935768; called by muse, mutect2, varscan2
- CORIN | c.2634C>T p.I878= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99904355; called by muse, mutect2, varscan2
- CRACD | c.3171C>A p.P1057= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV51723378; called by muse, mutect2, varscan2
- CSF2 | c.375G>A p.E125= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs748213403, COSV104396017, COSV99735826; called by muse, mutect2, varscan2
- DGKK | c.3228C>A p.A1076= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV101053197; called by muse, mutect2, varscan2
- DRD2 | c.561G>T p.P187= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100670118; called by muse, mutect2, varscan2
- EGFR | c.117G>A p.T39= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs777186292, COSV99294694; called by muse, mutect2, varscan2
- EPHB1 | c.1104G>T p.R368= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV101214317; called by muse, mutect2, varscan2
- GATAD2A | c.1053G>T p.A351= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV53072724, COSV99390677; called by muse, mutect2, varscan2
- GBP1 | c.636C>G p.T212= | Silent (SNP) | VAF 61/110 reads (55%) | catalogued as COSV100976299; called by muse, mutect2, varscan2
- HEATR5A | c.1383T>C p.P461= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV101120483; called by muse, mutect2, varscan2
- ISCU | c.450G>T p.L150= (on ENST00000311893 / NM_213595.4; = p.L125= on NM_014301.4) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100318483; called by muse, mutect2, varscan2
- IZUMO4 | c.285G>A p.K95= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV100643001, COSV100643010; called by muse, mutect2, varscan2
- KIF21A | c.3324A>G p.L1108= (on ENST00000361418 / NM_001378440.1; = p.L1095= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV100735626; called by muse, mutect2, varscan2
- KLHL20 | c.1281C>G p.L427= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV52941384, COSV99268656; called by muse, mutect2, varscan2
- KRT23 | c.1200C>T p.A400= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV99266356; called by muse, mutect2, varscan2
- KRTAP21-2 | c.63C>A p.S21= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100441253, COSV61684214; called by muse, mutect2, varscan2
- LDAH | c.114A>G p.Q38= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99425894; called by muse, mutect2, varscan2
- MAPK4 | c.1077G>C p.V359= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV101245942; called by muse, mutect2, varscan2
- MAS1L | c.237C>G p.A79= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101009723; called by muse, mutect2, varscan2
- METTL17 | c.1020C>T p.P340= | Silent (SNP) | VAF 107/243 reads (44%) | catalogued as rs1397613101, COSV100068710; called by muse, mutect2, varscan2
- MGAT4C | c.1239T>A p.V413= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100153349; called by muse, mutect2, varscan2
- MYCT1 | c.309C>T p.I103= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100924091; called by muse, mutect2, varscan2
- MYH11 | c.3021G>A p.R1007= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100260150; called by muse, mutect2, varscan2
- NAV3 | c.933T>A p.P311= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV99895079; called by muse, mutect2, varscan2
- NEK1 | c.2616A>T p.T872= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101455853; called by muse, mutect2, varscan2
- OFD1 | c.2661G>A p.V887= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as COSV100366510; called by muse, mutect2, varscan2
- OR5D13 | c.705G>A p.G235= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs192984177, COSV100687029; called by muse, mutect2, varscan2
- OR5M11 | c.843T>C p.S281= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV101602065; called by muse, mutect2, varscan2
- OR6Y1 | c.891G>C p.L297= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV100225494; called by muse, mutect2, varscan2
- ROBO3 | c.1050G>T p.V350= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV101185173; called by muse, mutect2, varscan2
- RPL28 | c.126A>T p.G42= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as COSV100689475; called by muse, mutect2, varscan2
- SEMA5B | c.681C>A p.A227= | Silent (SNP) | VAF 82/144 reads (57%) | catalogued as COSV99533091; called by muse, mutect2, varscan2
- SH2D1B | c.28C>T p.L10= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100854869, COSV63392434; called by muse, mutect2, varscan2
- SIM1 | c.1368G>T p.L456= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99492740; called by muse, varscan2
- SYMPK | c.726C>T p.F242= | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as COSV55611707; called by muse, mutect2, varscan2
- SYNDIG1 | c.273C>A p.I91= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV65234601, COSV65239612; called by muse, mutect2, varscan2
- TAGAP | c.582G>A p.L194= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV100487636; called by muse, mutect2, varscan2
- TTN | c.14643T>C p.S4881= (on ENST00000591111; = p.S3954= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV100628143; called by muse, mutect2, varscan2
- UBE3B | c.444C>T p.L148= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99784423; called by mutect2, varscan2
- VPS35 | c.1389G>A p.L463= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV100140783; called by muse, mutect2, varscan2
- ZEB2 | c.2466A>G p.K822= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100356817; called by muse, mutect2, varscan2
- ZMIZ1 | c.795C>T p.G265= | Silent (SNP) | VAF 69/157 reads (44%) | catalogued as COSV100566515; called by muse, mutect2, varscan2
- ZNF215 | c.837A>G p.K279= | Silent (SNP) | VAF 56/97 reads (58%) | catalogued as COSV99549902; called by muse, mutect2, varscan2
- DCHS2 | n.3391C>G | RNA (SNP) | VAF 106/242 reads (44%) | catalogued as rs774041400, COSV100253051; called by muse, mutect2, varscan2
- KCNC2 | c.*1989T>A | 3'UTR (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100129783; called by muse, mutect2, varscan2
- KDM4B | c.1115+674C>T | Intron (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99347351; called by muse, mutect2, varscan2
- MAPK10 | c.-127C>T | 5'UTR (SNP) | VAF 46/122 reads (38%) | catalogued as COSV60376861; called by muse, mutect2, varscan2
- MASP1 | c.1303+5276C>T | Intron (SNP) | VAF 21/100 reads (21%) | catalogued as rs749814050, COSV99962045; called by muse, mutect2, varscan2
- MIR587 | n.86C>A | RNA (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928493 G>T | 3'Flank (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100189307; called by muse, mutect2, varscan2
